TARGET case TARGET-30-PANWRR — Neuroblastoma (TARGET-NBL)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neuroepitheliomatous Neoplasms; Primary site: Other and ill-defined sites. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/d61abc8d-c674-58f2-af83-d18706e03514

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 8 years; Vital status: Dead; Days to death: 345 days.

Diagnoses (1)
1. Neuroblastoma, NOS: ICD-O-3 morphology code: 9500/3; ICD-10 code: C76.2; Tissue or organ of origin: Abdomen, NOS; Classification of tumor: primary; Age at diagnosis: 8.0 years (2,937 days); Year of diagnosis: 2005; Days to last follow up: 345 days; Cog neuroblastoma risk group: High Risk; Inpc grade: Differentiating; INSS stage: Stage 4; Mitosis karyorrhexis index: Low.
   Treatment given: Protocol identifier: ANBL00B1.
   Treatment given: Protocol identifier: A3973.

Follow-up (2 entries)
- Days to follow up: 267 days; Progression or recurrence anatomic site: Lymph node, NOS; Days to first event: 267 days; First event: Progression.
- Days to follow up: 345 days; Year of follow up: 2006.

Molecular and laboratory tests
- MYCN amplification: Not Amplified.
- Test: Normal; Ploidy: Diploid.

Biospecimens (2 samples)
- Sample TARGET-30-PANWRR-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
- Sample TARGET-30-PANWRR-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_NBL_ClinicalData_Discovery_20230523.xlsx (sheet Clinical Data):
- Overall Survival Time in Days: 345
- Protocol: ANBL00B1, A3973
- Ploidy: Diploid (DI=1)
- Ploidy Value: 1
- Histology: Unfavorable
- MKI: Low
- ICDO Description: Abdomen, NOS Abdominal wall, NOS Intra-abdominal site, NOS
